Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A0X9, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A0X9-01A (Primary Tumor).

TSS Patient ID: Sample Procurement: Date:

Gender: Date of Birth:
Vital Status: Date of Death:

Race: **White** Ethnicity: **Not Hispanic or Latino** Specific Ethnicity:

Histologic Subtype: **Colon adenocarcinoma** Date of Initial Path Dx:
Primary Site: **Colons** Anatomic Site: **Ascending Colon**
T Stage: **3** N Stage: **0** M Stage: **0** Overall Stage: **IIA**

Date of Normal Procurement:

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: ascending colon C18.2

lw
6/11/12

Source: NCI Genomic Data Commons file cdcd80f2-2835-4617-8a3c-aecadf55eca5 (TCGA-DM-A0X9.F323F54C-A86A-47DB-A26D-7541CB54A08E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).